Somatic mutation profile of tumor specimen TCGA-TQ-A7RF-01A (aliquot TCGA-TQ-A7RF-01A-11D-A33T-08) from TCGA case TCGA-TQ-A7RF, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 27.2 years (9,919 days).
Specimen TCGA-TQ-A7RF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7bc2952-6eef-4118-afde-9078ea0f4a2d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TQ-A7RF-10A (Blood Derived Normal), aliquot TCGA-TQ-A7RF-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5015a96c-765c-4313-88ac-997dd6990c19

The open-access MAF lists 30 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 7, Frame Shift Del 2, Splice Site 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DTD2 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 4/13 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs17097904; called by muse, mutect2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 82/196 reads (42%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.326T>C p.F109S | Missense Mutation (SNP) | VAF 124/138 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064796722, COSV52725602, COSV52838438; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK2 | c.2083G>A p.G695R | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100001018; called by muse, mutect2
- CD163 | c.2294C>T p.A765V | Missense Mutation (SNP) | VAF 43/288 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63136758; called by muse, mutect2, varscan2
- CEMIP2 | c.1482C>G p.I494M | Missense Mutation (SNP) | VAF 84/183 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100987340; called by muse, mutect2, varscan2
- CLCN4 | c.1661C>T p.A554V | Missense Mutation (SNP) | VAF 80/210 reads (38%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as COSV66468206; called by muse, mutect2, varscan2
- CSMD3 | c.5376A>G p.I1792M (on ENST00000297405 / NM_001363185.1; = p.I1688M on NM_052900.3) | Missense Mutation (SNP) | VAF 52/360 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99831663; called by muse, varscan2
- CSMD3 | c.5282C>T p.P1761L (on ENST00000297405 / NM_001363185.1; = p.P1657L on NM_052900.3) | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99831670; called by muse, varscan2
- EPB41L3 | c.990C>G p.N330K | Missense Mutation (SNP) | VAF 12/393 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100548755; called by muse, mutect2
- NBEA | c.3362del p.N1121Mfs*9 | Frame Shift Del (DEL) | VAF 21/62 reads (34%) | catalogued as rs763376147; called by mutect2, varscan2
- OR10W1 | c.584T>A p.I195K | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV101223649; called by muse, mutect2, varscan2
- OR4C13 | c.746T>A p.F249Y | Missense Mutation (SNP) | VAF 149/382 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV101634164; called by muse, mutect2, varscan2
- PCDHB6 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 196/445 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50691548; called by muse, varscan2
- PLEKHA8 | c.169G>C p.D57H | Missense Mutation (SNP) | VAF 117/264 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99321670; called by muse, mutect2, varscan2
- PRG4 | c.2933C>T p.T978I | Missense Mutation (SNP) | VAF 131/326 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV100798177; called by muse, mutect2, varscan2
- PTH1R | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs200304786, COSV57317224; called by muse, mutect2, varscan2
- SLC10A7 | c.262A>G p.I88V | Missense Mutation (SNP) | VAF 95/168 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99390409; called by muse, mutect2, varscan2
- VIRMA | c.2072T>G p.I691S | Missense Mutation (SNP) | VAF 93/218 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as COSV99888157; called by muse, mutect2, varscan2
- BANK1 | c.764_765del p.X255_splice | Splice Site (DEL) | VAF 77/216 reads (36%) | called by pindel, varscan2
- PHF10 | c.567_568del p.K190Sfs*2 | Frame Shift Del (DEL) | VAF 58/97 reads (60%) | called by mutect2, pindel, varscan2
- CDHR5 | c.660C>T p.T220= | Silent (SNP) | VAF 59/121 reads (49%) | catalogued as rs778453058, COSV62764261; called by muse, mutect2, varscan2
- EMID1 | c.951G>A p.G317= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV100468874; called by muse, mutect2, varscan2
- FLG2 | c.5478C>T p.H1826= | Silent (SNP) | VAF 254/496 reads (51%) | catalogued as rs557753791, COSV101165793; called by muse, mutect2, varscan2
- MDC1 | c.6195G>T p.L2065= | Silent (SNP) | VAF 91/263 reads (35%) | catalogued as COSV100902745; called by muse, mutect2, varscan2
- MORC1 | c.1188C>T p.G396= | Silent (SNP) | VAF 70/179 reads (39%) | catalogued as rs767418985, COSV51716803; called by muse, mutect2, varscan2
- NRP1 | c.84C>T p.G28= | Silent (SNP) | VAF 37/134 reads (28%) | catalogued as rs752803831, COSV99588389; called by muse, mutect2, varscan2
- OR4C13 | c.747T>C p.F249= | Silent (SNP) | VAF 153/384 reads (40%) | catalogued as rs781926174, COSV101634165; called by muse, mutect2, varscan2
- CLEC4C | c.-2C>A | 5'UTR (SNP) | VAF 23/163 reads (14%) | catalogued as COSV100665426; called by muse, mutect2, varscan2
- HUWE1 | c.1490-643C>T | Intron (SNP) | VAF 43/93 reads (46%) | called by muse, mutect2, varscan2
